Gene-level copy-number profile of specimen HCM-BROD-0234-C49-85M from HCMI case HCM-BROD-0234-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 76.5 years (27,950 days).
Specimen HCM-BROD-0234-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3fa4ec30-91a0-4e00-9dc2-208457f90638.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0234-C49-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,761 have no estimate.
https://portal.gdc.cancer.gov/files/906c7332-0c98-4adf-a8ac-5a0b37d87b94

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 19; copy number 2: 3,995; copy number 3: 10,925; copy number 4: 11,693; copy number 5: 13,167; copy number 6: 12,977; copy number 7: 4,498; copy number 8: 741; copy number 9: 436; copy number 10: 228; copy number 11: 65; copy number 21: 23; copy number 28: 34; copy number 33: 2; copy number 35: 6; copy number 38: 14; copy number 40: 9; copy number 43: 14; copy number 49: 16.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 183 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:96,593,170–96,642,787, 1 gene, copy number 11 (within-gene range 10–11): KANSL3.
- chr2:199,608,068–201,229,406, 51 genes, copy number 11: LINC01877, SEPHS1P6, FTCDNL1, AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1, SPATS2L, RNY4P34, AC012459.1, KCTD18, SGO2, AOX1, AOX3P, AOX3P-AOX2P, LINC01792, AOX2P, RNU1-133P, BZW1-AS1, BZW1, RNU6-31P, BICD1P1, RNA5SP115, CLK1, Y_RNA, PPIL3, RNU6-312P, NIF3L1, RNU6-762P, ORC2, AC005037.1, FAM126B, HNRNPA1P35, RPL23AP30, NDUFB3, RNU6-1206P, Metazoa_SRP, AC007272.1, RPL17P10, CFLAR, IMPDH1P10, CFLAR-AS1, RNU7-45P, RPL38P5, AC007283.1, CASP10, MTND5P25, MTND4P23, MTND4LP13.
- chr8:50,859,530–52,022,974, 13 genes, copy number 28–35: AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3.
- chr9:99,183,373–99,230,615, 4 genes, copy number 11: AL162427.1, RN7SL794P, ALG2, SEC61B.
- chr9:100,302,077–100,976,682, 9 genes, copy number 11: TEX10, MSANTD3, MSANTD3-TMEFF1, TMEFF1, CAVIN4, RN7SKP87, ACTG1P19, AL162395.1, GAPDHP26.
- chr11:28,702,607–31,369,810, 25 genes, copy number 21–33 (within-gene range 3–33): LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1.
- chr11:31,812,307–35,530,300, 80 genes, copy number 28–49 (within-gene range 3–49) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
